FM case AD12068 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/9f01901b-0f82-4d0c-b256-c5e6dcf00cad

Female, 29.8 years: Melanoma, NOS (ICD-O-3 8720/3) of the eye; primary biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
